CCDI case PBCSPA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/197f921e-2a32-4e8e-8528-4aa6d5c4c5d2

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Spindle cell rhabdomyosarcoma: ICD-O-3 morphology code: 8912/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 4.8 years (1,738 days).

Biospecimens (3 samples)
- Sample 0DYKRJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DYKS4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYKSD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
